Somatic mutation profile of tumor specimen MMRF_1151_1_BM_CD138pos (aliquot MMRF_1151_1_BM_CD138pos_T2_TSE61_K03198) from MMRF case MMRF_1151, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.8 years (26,238 days).
Specimen MMRF_1151_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d16f2cc7-af32-4a39-a0a9-dc28a2e16b47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1151_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1151_1_PB_Whole_C1_TSE61_K03199; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efe2b5b6-ac72-448b-bcc6-f925185a934b

The open-access MAF lists 95 somatic variants for this specimen: 35 protein-altering or splice-affecting, 14 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 34, Missense Mutation 30, Silent 14, 3'Flank 4, RNA 3, Frame Shift Del 2, 5'UTR 2, Intron 2, Frame Shift Ins 1, 5'Flank 1, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10A | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775035574, COSV63516207; called by muse, mutect2, varscan2
- CACNA1C | c.5941C>T p.R1981* (on ENST00000399634 / NM_001167625.1; = p.R1910* on NM_000719.7) | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | catalogued as rs1556291640, COSV59741294, COSV59776352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASP10 | c.554T>G p.I185R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753049035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.3802G>A p.G1268R | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762090092, COSV68021677; called by muse, mutect2, varscan2
- FBN3 | c.2924G>A p.R975Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs771029771; called by muse, mutect2, varscan2
- IGSF5 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs371108598; called by muse, mutect2, varscan2
- KRT84 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs948674123, COSV57772209; called by muse, mutect2, varscan2
- KYNU | c.268del p.E90Nfs*2 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as COSV51580540; called by mutect2, pindel, varscan2
- LNX1 | c.428G>A p.R143H (on ENST00000263925 / NM_001126328.3; = p.R47H on NM_032622.2) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as rs762969714; called by muse, mutect2, varscan2
- MROH9 | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1308038072, COSV63010747; called by muse, mutect2, varscan2
- PSD | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as rs748273396; called by muse, mutect2, varscan2
- ZNF470 | c.138T>G p.S46R | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs1293049875; called by muse, mutect2, varscan2
- ABRAXAS1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- B3GNT6 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BEND2 | c.2398T>C p.*800Rext*11 | Nonstop Mutation (SNP) | VAF 40/40 reads (100%) | called by muse, mutect2, varscan2
- BRD1 | c.766T>C p.W256R | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP350 | c.7940T>G p.L2647R | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CUBN | c.4270G>A p.D1424N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- DGKH | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ELL3 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM83B | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- GUCY1A1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- HTR3A | c.1295G>C p.R432P | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- IZUMO1R | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- LGR5 | c.14G>C p.R5P | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCLN | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- OSGEPL1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- POFUT1 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRPF19 | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SCN4A | c.4685C>T p.T1562I | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- SLITRK3 | c.1285T>G p.W429G | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TENT5C | c.720_721del p.G241Rfs*42 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by pindel, varscan2
- ZMPSTE24 | c.1220dup p.T408Nfs*8 | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- ZNF429 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL14A1 | c.346A>C p.R116= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- DENND2B | c.414G>A p.T138= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as rs1370938884, COSV58208349; called by muse, mutect2, varscan2
- DNAJC19 | c.141T>C p.G47= | Silent (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- GAD1 | c.1137G>A p.G379= | Silent (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- GALNT15 | c.444G>A p.E148= | Silent (SNP) | VAF 57/109 reads (52%) | catalogued as rs1464930274; called by muse, mutect2, varscan2
- IGF1R | c.2100C>T p.C700= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as rs767179117, COSV99163314; called by muse, mutect2, varscan2
- IRX1 | c.1323C>T p.L441= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs370521377, COSV57358222; called by muse, mutect2
- KIAA0319 | c.162C>T p.V54= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs760317255, COSV65501205; called by muse, mutect2, varscan2
- LAMC3 | c.585C>T p.S195= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as rs760411569; called by muse, mutect2, varscan2
- LTB | c.220C>T p.L74= | Silent (SNP) | VAF 63/130 reads (48%) | catalogued as rs562961152; called by muse, mutect2, varscan2
- PLEKHG2 | c.225C>T p.S75= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs927233443; called by muse, mutect2, varscan2
- POLE | c.5388G>A p.K1796= | Silent (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- PTPN21 | c.1518G>T p.A506= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- SHC3 | c.693G>A p.T231= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs746827118, COSV65437926; called by muse, mutect2, varscan2
- ADAMTS9 | c.*848C>T | 3'UTR (SNP) | VAF 58/141 reads (41%) | called by muse, mutect2, varscan2
- AP5B1 | c.*624T>G | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- CDKN2B-AS1 | n.1589T>G | RNA (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2936872 G>T | 3'Flank (SNP) | VAF 32/72 reads (44%) | catalogued as rs1371569375; called by muse, mutect2, varscan2
- FER1L4 | n.769del | RNA (DEL) | VAF 71/156 reads (46%) | catalogued as rs375189678; called by mutect2, pindel, varscan2
- FOXO1 | c.*3267T>A | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- FOXO1 | c.*2585T>C | 3'UTR (SNP) | VAF 15/67 reads (22%) | catalogued as rs916625312; called by muse, mutect2, varscan2
- GAD1 | c.*915G>A | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- HPS1 | c.937+87C>T | Intron (SNP) | VAF 66/117 reads (56%) | catalogued as rs1341432797; called by muse, mutect2, varscan2
- HS6ST1 | c.*123G>A | 3'UTR (SNP) | VAF 28/155 reads (18%) | catalogued as rs906583143; called by muse, mutect2, varscan2
- IMP3 | c.*408T>C | 3'UTR (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- INVS | c.*325T>G | 3'UTR (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- KBTBD11 | c.*3860G>A | 3'UTR (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- KIF1B | c.*282A>G | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, varscan2
- KLHL1 | c.*820C>A | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as COSV64772807; called by muse, mutect2, varscan2
- KLHL7 | c.-78A>G | 5'UTR (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- KLK2 | chr19:50882111 C>T | 3'Flank (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- LCA5 | c.*698A>G | 3'UTR (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- LIN28B | c.*1429del | 3'UTR (DEL) | VAF 22/51 reads (43%) | called by mutect2, varscan2
- LIX1 | c.*1051T>C | 3'UTR (SNP) | VAF 62/91 reads (68%) | called by muse, mutect2, varscan2
- LZTS1 | c.-32C>T | 5'UTR (SNP) | VAF 39/79 reads (49%) | catalogued as rs377470662, COSV56117971; called by muse, mutect2, varscan2
- MYO18B | chr22:26030637 C>T | 3'Flank (SNP) | VAF 13/37 reads (35%) | called by muse, varscan2
- ORAI2 | c.*2189C>T | 3'UTR (SNP) | VAF 13/28 reads (46%) | catalogued as rs935347948; called by muse, varscan2
- OTUD4 | c.*1240C>T | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- PANK2 | c.*169T>G | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- PCDH9 | c.*1484A>G | 3'UTR (SNP) | VAF 52/104 reads (50%) | called by muse, mutect2, varscan2
- PDE4A | c.*1048C>G | 3'UTR (SNP) | VAF 34/116 reads (29%) | called by muse, varscan2
- PRSS12 | chr4:118279679 A>G | 3'Flank (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- RNU6-502P | chr6:26522394 A>C | 5'Flank (SNP) | VAF 220/531 reads (41%) | called by muse, mutect2, varscan2
- SEC14L1 | c.*2262T>G | 3'UTR (SNP) | VAF 234/550 reads (43%) | called by mutect2, varscan2
- SEMA3C | c.*515C>T | 3'UTR (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- SLC35A2 | c.1164-440T>G | Intron (SNP) | VAF 44/44 reads (100%) | called by muse, mutect2, varscan2
- SOST | c.*1315T>A | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- SPRED1 | c.*2526A>G | 3'UTR (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- TENT5B | c.*490G>A | 3'UTR (SNP) | VAF 67/129 reads (52%) | called by muse, mutect2, varscan2
- TRHDE-AS1 | n.3490A>T | RNA (SNP) | VAF 49/88 reads (56%) | called by muse, mutect2, varscan2
- UBN2 | c.*1715T>G | 3'UTR (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- ULK1 | c.*763A>T | 3'UTR (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- WTAP | c.*265A>C | 3'UTR (SNP) | VAF 21/21 reads (100%) | called by muse, mutect2, varscan2
- ZIC5 | c.*1231G>T | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- ZNF282 | c.*876G>T | 3'UTR (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- ZNF572 | c.*528T>G | 3'UTR (SNP) | VAF 12/20 reads (60%) | called by muse, varscan2
- ZNF572 | c.*721C>T | 3'UTR (SNP) | VAF 12/19 reads (63%) | called by muse, varscan2
- ZNF572 | c.*768T>G | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- ZNF572 | c.*1127T>C | 3'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, varscan2
- ZNF770 | c.*474T>C | 3'UTR (SNP) | VAF 22/36 reads (61%) | called by muse, mutect2, varscan2
